Gene-level copy-number profile of tumor specimen C3N-00953-01 from CPTAC case C3N-00953, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 41.4 years (15,137 days).
Specimen C3N-00953-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2aec9eee-71cc-4be2-9103-46449a1a4794.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00953-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/c8fb1e79-8851-4b16-b054-3034b70ad72a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 117; copy number 2: 9,480; copy number 3: 310; copy number 4: 45,000; copy number 5: 277; copy number 6: 3,649; copy number 7: 11; copy number 8: 7; copy number 9: 1; copy number 10: 8; copy number 11: 9.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr14:35,538,352–35,932,325, 8 genes (within-gene range 0–2): RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2.
- chr14:43,592,142–44,386,064, 6 genes (within-gene range 0–2): AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–157,887, 16 genes, copy number 10–11: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr14:18,395,626–18,412,264, 1 gene, copy number 9: CR383658.2.
- chr21:8,603,547–8,603,984, 1 gene, copy number 10: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
